Somatic mutation profile of tumor specimen ALCH-AEF0-TTP1-A (aliquot ALCH-AEF0-TTP1-A-1-0-D-A605-36) from ALCHEMIST case ALCH-AEF0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.2 years (29,669 days).
Specimen ALCH-AEF0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8b85fb0-8fcd-4027-9d48-756fcfb7fb87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEF0-NB1-A (Blood Derived Normal), aliquot ALCH-AEF0-NB1-A-1-0-D-A605-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d916434-036b-46d2-bce1-72391e956db5

The open-access MAF lists 64 somatic variants for this specimen: 48 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 9, 3'UTR 3, Frame Shift Del 3, 5'UTR 2, Nonsense Mutation 2, Intron 2, In Frame Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 518/1432 reads (36%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- BCL11A | c.1633G>A p.E545K (on ENST00000335712 / NM_001365609.1; = p.E579K on NM_018014.4) | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.059); catalogued as COSV59639329; called by muse, mutect2
- CACNA1F | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 29/1010 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100544898; called by muse, mutect2
- CDX4 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 29/387 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.602); catalogued as COSV100999152, COSV65171389; called by muse, mutect2
- HDAC6 | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 24/480 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs782668755, COSV61927582; called by muse, mutect2
- IGHV1OR21-1 | c.281C>A p.S94Y | Missense Mutation (SNP) | VAF 68/1106 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs1244211111; called by muse, mutect2
- IGSF10 | c.2074G>T p.E692* | Nonsense Mutation (SNP) | VAF 59/331 reads (18%) | catalogued as COSV56788740, COSV99192177; called by muse, mutect2, varscan2
- MMP16 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs866043551, COSV54176946, COSV99688155; called by muse, mutect2
- MMP16 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1233813645, COSV54182591; called by muse, mutect2
- MUC5B | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs780459524; called by muse, mutect2, varscan2
- NALCN | c.3572C>T p.P1191L | Missense Mutation (SNP) | VAF 23/383 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV51940911; called by muse, mutect2
- NOS3 | c.1507G>A p.V503M | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774609359; called by muse, mutect2, varscan2
- OR51E2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 51/1145 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138231892, COSV101211403; called by muse, mutect2
- OSBP2 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 27/488 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs921997600, COSV60240074; called by muse, mutect2
- RLBP1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 103/639 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51529591; called by muse, mutect2, varscan2
- RYR2 | c.13988G>A p.R4663Q | Missense Mutation (SNP) | VAF 53/355 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1483438745, COSV63688528; called by muse, mutect2, varscan2
- SAGE1 | c.562A>G p.T188A | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs1556600728; called by muse, mutect2, varscan2
- SH3KBP1 | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 62/424 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1488429557; called by muse, mutect2, varscan2
- SLC24A3 | c.1336G>T p.E446* | Nonsense Mutation (SNP) | VAF 50/241 reads (21%) | catalogued as COSV60119893; called by muse, varscan2
- SLC27A6 | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1056678255, COSV99322690; called by muse, mutect2, varscan2
- SUPT3H | c.295C>T p.R99C (on ENST00000371460 / NM_181356.3; = p.R88C on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/291 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373980353; called by muse, mutect2, varscan2
- ALDH1L1 | c.2228A>G p.D743G | Missense Mutation (SNP) | VAF 58/344 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARMCX5 | c.684G>T p.R228S | Missense Mutation (SNP) | VAF 18/538 reads (3%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.792); called by muse, mutect2
- ASB5 | c.626G>T p.C209F | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CES2 | c.1070A>G p.Y357C | Missense Mutation (SNP) | VAF 55/340 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- CRLF2 | c.575A>C p.D192A | Missense Mutation (SNP) | VAF 103/767 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYP11B2 | c.1248G>T p.L416F | Missense Mutation (SNP) | VAF 46/864 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- EHBP1 | c.1145A>G p.N382S | Missense Mutation (SNP) | VAF 47/263 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FASN | c.3733-1G>A p.X1245_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- GBF1 | c.796C>G p.P266A | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2
- GPATCH8 | c.113T>G p.I38R | Missense Mutation (SNP) | VAF 106/640 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- GPRC5C | c.102A>T p.G34= | Splice Region (SNP) | VAF 18/364 reads (5%) | called by muse, mutect2
- ITGAE | c.2324G>C p.C775S | Missense Mutation (SNP) | VAF 87/561 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- MAD1L1 | c.1340G>T p.S447I | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MED12 | c.5886_5888delinsAC p.M1963Rfs*23 | Frame Shift Del (DEL) | VAF 55/414 reads (13%) | called by pindel, varscan2*
- MMP16 | c.84G>C p.W28C | Missense Mutation (SNP) | VAF 95/505 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- NEO1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 37/671 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- PCDHB16 | c.1402C>A p.L468M | Missense Mutation (SNP) | VAF 69/1632 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.604); called by muse, mutect2
- PIK3CB | c.697A>T p.T233S | Missense Mutation (SNP) | VAF 51/278 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- POLR2B | c.927del p.F309Lfs*10 | Frame Shift Del (DEL) | VAF 11/69 reads (16%) | called by mutect2, pindel, varscan2
- RABGAP1 | c.2768C>G p.A923G | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.118); called by muse, mutect2
- RANBP2 | c.3932A>G p.N1311S | Missense Mutation (SNP) | VAF 107/619 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBM10 | c.2541del p.F848Sfs*38 | Frame Shift Del (DEL) | VAF 74/321 reads (23%) | called by mutect2, pindel, varscan2
- RPS19BP1 | c.243G>T p.R81S | Missense Mutation (SNP) | VAF 20/480 reads (4%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2
- SLC2A4 | c.1447T>C p.F483L | Missense Mutation (SNP) | VAF 62/1230 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2
- TLL1 | c.2767T>A p.S923T | Missense Mutation (SNP) | VAF 40/798 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- USP7 | c.2752G>T p.V918F | Missense Mutation (SNP) | VAF 60/606 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- WDR19 | c.788A>T p.E263V | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- APBA2 | c.93C>T p.S31= | Silent (SNP) | VAF 102/462 reads (22%) | catalogued as rs557200678, COSV68788505; called by muse, mutect2, varscan2
- DIAPH2 | c.1065T>C p.R355= | Silent (SNP) | VAF 64/351 reads (18%) | called by muse, mutect2, varscan2
- GATB | c.1431G>A p.K477= | Silent (SNP) | VAF 19/247 reads (8%) | catalogued as rs777192177; called by muse, mutect2
- H2AC12 | c.324C>G p.V108= | Silent (SNP) | VAF 18/366 reads (5%) | catalogued as COSV63616772; called by muse, mutect2
- PGAM4 | c.633G>A p.P211= | Silent (SNP) | VAF 187/1111 reads (17%) | catalogued as rs1557229171, COSV58449675; called by muse, mutect2, varscan2
- PRRG1 | c.441C>G p.G147= | Silent (SNP) | VAF 20/363 reads (6%) | called by muse, mutect2
- SEZ6L2 | c.2406C>T p.G802= (on ENST00000308713 / NM_001114099.3; = p.G732= on NM_012410.4) | Silent (SNP) | VAF 96/505 reads (19%) | catalogued as rs1255344822; called by muse, mutect2, varscan2
- SI | c.2967C>G p.R989= | Silent (SNP) | VAF 27/790 reads (3%) | called by muse, mutect2
- ZNF428 | c.396G>T p.G132= | Silent (SNP) | VAF 54/204 reads (26%) | called by muse, mutect2, varscan2
- ACADM | c.-18G>A | 5'UTR (SNP) | VAF 9/100 reads (9%) | catalogued as COSV63720075; called by muse, mutect2
- BOLL | c.*56G>A | 3'UTR (SNP) | VAF 19/261 reads (7%) | catalogued as rs747368316, COSV99987229; called by muse, mutect2
- BRWD3 | c.-28G>A | 5'UTR (SNP) | VAF 8/53 reads (15%) | catalogued as rs753373070; called by muse, mutect2, varscan2
- EFEMP2 | c.-7-22A>T | Intron (SNP) | VAF 26/156 reads (17%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5181A>C | Intron (SNP) | VAF 164/880 reads (19%) | called by muse, mutect2, varscan2
- NUP62 | c.*656G>A | 3'UTR (SNP) | VAF 32/114 reads (28%) | called by muse, mutect2
- RTL8B | c.*301G>T | 3'UTR (SNP) | VAF 16/408 reads (4%) | catalogued as COSV101195536; called by muse, mutect2
